MMRF case MMRF_2118 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b547ac6a-1df0-482a-af70-986b96b70af3

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.5 years (23,204 days); ISS stage: II; Days to last known disease status: 911 days (2.5 years); Days to last follow up: 911 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 705 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Elotuzumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 624 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 5.8 g/dL; Beta 2 Microglobulin 3.9 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 6.66 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 1.9 mmol/L; Albumin 22 g/L; Total Protein 7.6 g/dL; Glucose 11.2 mmol/L.
- Day 96 (ECOG 1): M Protein 0.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 138 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 215 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 1.86 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.94 mmol/L.
- Day 188 (ECOG 0): Hemoglobin 7.01 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 7.15 mmol/L.
- Day 274 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 6.91 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 2.58 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 14 ×10⁹/L; Absolute Neutrophil 10.8 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 9.85 mmol/L.
- Day 372 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 8.25 g/L; Beta 2 Microglobulin 2.08 µg/mL; Hemoglobin 6.45 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Glucose 9.02 mmol/L.
- Day 442 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 9.1 g/L; Immunoglobulin A 2.29 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.46 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 7.37 mmol/L.
- Day 541 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin M 0.52 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.
- Day 632 (ECOG 1): M Protein 0.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.49 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 3.89 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 151 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 4.62 mmol/L.
- Day 712 (ECOG 1): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.2 mg/dL; Immunoglobulin G 36 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 5.58 µg/mL; Hemoglobin 6.63 mmol/L; Leukocytes 12.4 ×10⁹/L; Absolute Neutrophil 9.3 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 165 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 8.9 g/dL; Glucose 6.71 mmol/L.
- Day 824 (ECOG 1): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.88 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 4.33 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 148 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.05 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 7.21 mmol/L.
- Day 911 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.62 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 2.63 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 0.63 µg/mL; Hemoglobin 5.89 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 187 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 1.95 mmol/L; Albumin 30 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.

Other clinical attributes
- Day 1: Weight: 80 kg; Height: 173 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2118_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2118_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
